Somatic mutation profile of tumor specimen TCGA-4X-A9FC-01A (aliquot TCGA-4X-A9FC-01A-11D-A423-09) from TCGA case TCGA-4X-A9FC, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 50.4 years (18,418 days).
Specimen TCGA-4X-A9FC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e20fe3a0-023e-4d59-8472-c8b99547f084.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4X-A9FC-10A (Blood Derived Normal), aliquot TCGA-4X-A9FC-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbffe485-c4e5-4f46-8201-dbb2dde00f80

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 28/508 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- UPRT | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV64912727; called by muse, mutect2
- CYB5RL | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HUWE1 | c.6068C>G p.T2023S | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); called by muse, mutect2
